Somatic mutation profile of tumor specimen MMRF_2517_1_BM_CD138pos (aliquot MMRF_2517_1_BM_CD138pos_T1_KHS5U_L12865) from MMRF case MMRF_2517, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.0 years (20,811 days).
Specimen MMRF_2517_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3e88ceb-d25f-47fc-aff8-bdbc3c1eb303.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2517_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2517_1_PB_Whole_C2_KHS5U_L12866; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f60cb59-ae09-4a54-9b61-4eb08af719f8

The open-access MAF lists 59 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 16, Intron 9, Silent 8, Nonsense Mutation 3, Frame Shift Del 1, Splice Region 1, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 238/539 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC66 | c.2552G>A p.R851Q (on ENST00000394672 / NM_001353147.1; = p.R817Q on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/181 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764642777; called by muse, mutect2, varscan2
- CPNE1 | c.586G>A p.V196I (on ENST00000352393; = p.V201I on NM_003915.5) | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs967240640; called by muse, mutect2, varscan2
- DNAH10 | c.1567G>A p.E523K (on ENST00000409039; = p.E462K on NM_207437.3) | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.294); catalogued as rs757900300; called by muse, mutect2, varscan2
- IGHJ4 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 10/53 reads (19%) | PolyPhen possibly damaging (0.795); catalogued as rs183645858; called by muse, varscan2
- IGLV3-1 | c.302A>G p.E101G | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs532827838; called by muse, mutect2, varscan2
- MARCHF6 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 55/184 reads (30%) | catalogued as rs1413548708; called by muse, mutect2, varscan2
- MYH14 | c.3728G>A p.R1243Q | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs1451515281; called by muse, mutect2, varscan2
- OTOP3 | c.587G>A p.W196* | Nonsense Mutation (SNP) | VAF 90/176 reads (51%) | catalogued as rs1166943640; called by muse, mutect2, varscan2
- ZNF890P | n.478G>T | Splice Region (SNP) | VAF 17/103 reads (17%) | catalogued as rs765932280; called by muse, mutect2, varscan2
- ADAMTS20 | c.2039G>C p.G680A | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ARID1A | c.2116_2125del p.V706Lfs*33 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- CTNND2 | c.3337A>T p.M1113L | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV2-70D | c.153T>A p.S51R | Missense Mutation (SNP) | VAF 57/60 reads (95%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNH6 | c.880A>C p.S294R | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MIPOL1 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- N4BP3 | c.1075A>C p.S359R | Missense Mutation (SNP) | VAF 112/173 reads (65%) | SIFT tolerated (0.53); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OGT | c.135_140del p.M45_L47delinsI | In Frame Del (DEL) | VAF 150/178 reads (84%) | called by mutect2, pindel, varscan2
- OR8B3 | c.321dup p.V108Cfs*4 | Frame Shift Ins (INS) | VAF 97/253 reads (38%) | called by mutect2, pindel, varscan2
- RNF144B | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- RNF183 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2
- SETD1A | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.022); called by muse, mutect2
- SLC30A10 | c.945C>A p.N315K | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); called by muse, mutect2
- TANK | c.488T>G p.L163* | Nonsense Mutation (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 146/272 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- BTBD16 | c.579C>G p.G193= | Silent (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- CGN | c.1566C>T p.Y522= | Silent (SNP) | VAF 20/27 reads (74%) | called by muse, mutect2, varscan2
- IGHJ5 | c.36C>A p.V12= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs552973223; called by muse, varscan2
- MRPS27 | c.612T>C p.F204= | Silent (SNP) | VAF 300/455 reads (66%) | called by muse, mutect2, varscan2
- NUDT19 | c.418C>T p.L140= | Silent (SNP) | VAF 94/294 reads (32%) | called by muse, mutect2, varscan2
- PCDHGC4 | c.306C>T p.C102= | Silent (SNP) | VAF 176/515 reads (34%) | called by muse, mutect2, varscan2
- TERF2IP | c.483C>T p.N161= | Silent (SNP) | VAF 96/211 reads (45%) | called by muse, mutect2, varscan2
- TTLL10 | c.780C>T p.P260= (on ENST00000379289 / NM_001130045.2; = p.P187= on NM_153254.3) | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs774536459, COSV64961007; called by muse, mutect2, varscan2
- C11orf87 | c.*2552G>C | 3'UTR (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- C2orf68 | c.*443C>G | 3'UTR (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- CENPC | c.2131+105A>C | Intron (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2
- CHFR | c.1684-133A>C | Intron (SNP) | VAF 22/29 reads (76%) | called by muse, mutect2, varscan2
- CHIC1 | c.*1262T>A | 3'UTR (SNP) | VAF 47/49 reads (96%) | called by muse, mutect2, varscan2
- DEPDC7 | c.464+74del | Intron (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel
- DUSP2 | c.511-114G>A | Intron (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- FCHSD2 | c.-177T>C | 5'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- FRMPD3 | c.*69C>A | 3'UTR (SNP) | VAF 173/176 reads (98%) | called by muse, varscan2
- KLHL3 | c.*3719C>T | 3'UTR (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- MEF2C | c.*1724C>T | 3'UTR (SNP) | VAF 63/195 reads (32%) | called by muse, mutect2, varscan2
- MPP2 | c.*1437C>A | 3'UTR (SNP) | VAF 61/142 reads (43%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.2400+1109G>A | Intron (SNP) | VAF 32/72 reads (44%) | called by mutect2, varscan2
- PPP1R3D | c.*600del | 3'UTR (DEL) | VAF 40/90 reads (44%) | called by mutect2, pindel, varscan2
- PRR16 | c.159+16527A>T | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- RAC2 | c.107+583C>T | Intron (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.*372G>A | 3'UTR (SNP) | VAF 48/209 reads (23%) | called by muse, mutect2, varscan2
- RCAN1 | c.*475C>T | 3'UTR (SNP) | VAF 56/197 reads (28%) | catalogued as rs968913926; called by muse, mutect2, varscan2
- RP1 | c.*305G>A | 3'UTR (SNP) | VAF 44/87 reads (51%) | called by muse, mutect2, varscan2
- SFMBT2 | c.*3851A>T | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- SLC6A12 | c.*503G>A | 3'UTR (SNP) | VAF 70/154 reads (45%) | catalogued as rs896627613; called by muse, mutect2, varscan2
- SRPK1 | c.74+253T>A | Intron (SNP) | VAF 73/156 reads (47%) | called by muse, mutect2, varscan2
- STEAP4 | c.984+187T>A | Intron (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- TENT5C | c.*3609C>T | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- ZNF716 | c.*226dup | 3'UTR (INS) | VAF 18/60 reads (30%) | called by mutect2, varscan2
- ZNF84 | c.*634A>G | 3'UTR (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
